Somatic mutation profile of tumor specimen HCM-BROD-0097-C15-06A (aliquot HCM-BROD-0097-C15-06A-11D-A78T-36) from HCMI case HCM-BROD-0097-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; AJCC pathologic stage: Stage IV; Tumor grade: GX; Age at diagnosis: 73.5 years (26,828 days).
Specimen HCM-BROD-0097-C15-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a2b1b812-57aa-4238-9c8d-1e589cf2e0ec.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0097-C15-10A (Blood Derived Normal), aliquot HCM-BROD-0097-C15-10A-01D-A78T-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e53c7139-3ab6-4bfc-988e-fa87c786e177

The open-access MAF lists 155 somatic variants for this specimen: 108 protein-altering or splice-affecting, 34 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 97, Silent 34, Nonsense Mutation 5, 3'UTR 3, Splice Region 3, 5'Flank 3, RNA 2, Intron 2, 5'UTR 2, Frame Shift Del 2, 3'Flank 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.1009C>T p.R337C | Missense Mutation (SNP) | VAF 229/281 reads (81%) | hotspot (GDC flag); SIFT tolerated (0.09); PolyPhen benign (0.344); catalogued as rs587782529, CM981929, COSV52669243, COSV52718762, COSV52810068, COSV52816817; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AKR1B15 | c.176C>T p.A59V | Missense Mutation (SNP) | VAF 224/454 reads (49%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.667); catalogued as rs201762103; called by muse, mutect2, varscan2
- ARL5B | c.400A>G p.T134A | Missense Mutation (SNP) | VAF 35/106 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.029); catalogued as COSV66011115; called by muse, mutect2, varscan2
- BORCS6 | c.838C>T p.R280C | Missense Mutation (SNP) | VAF 117/489 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.111); catalogued as COSV66504784; called by muse, mutect2, varscan2
- CACNA1G | c.577C>T p.R193W | Missense Mutation (SNP) | VAF 57/216 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1373767246, COSV61719733; called by muse, mutect2, varscan2
- CCNDBP1 | c.169+4A>G | Splice Region (SNP) | VAF 28/152 reads (18%) | catalogued as rs779646742; called by muse, mutect2, varscan2
- CD2AP | c.1409A>G p.K470R | Missense Mutation (SNP) | VAF 139/312 reads (45%) | SIFT tolerated (0.24); PolyPhen benign (0.006); catalogued as rs940356500; called by muse, mutect2, varscan2
- CNP | c.1058G>A p.R353Q | Missense Mutation (SNP) | VAF 90/194 reads (46%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as rs782146999; called by muse, mutect2, varscan2
- CORO2B | c.680G>A p.R227Q | Missense Mutation (SNP) | VAF 29/161 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.045); catalogued as rs144987289, COSV55958776; called by muse, mutect2, varscan2
- DIAPH3 | c.1324C>T p.Q442* (on ENST00000400324 / NM_001042517.2; = p.Q179* on NM_030932.3) | Nonsense Mutation (SNP) | VAF 24/129 reads (19%) | catalogued as COSV57364866; called by muse, mutect2, varscan2
- DPYS | c.1086A>T p.K362N | Missense Mutation (SNP) | VAF 208/938 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.486); catalogued as COSV60907400; called by mutect2, varscan2
- EGR1 | c.1481C>T p.S494L | Missense Mutation (SNP) | VAF 102/119 reads (86%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.024); catalogued as COSV53520886; called by muse, mutect2, varscan2
- EHBP1 | c.3538G>C p.D1180H | Missense Mutation (SNP) | VAF 46/120 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762739434; called by muse, mutect2, varscan2
- EIF2B5 | c.1819G>A p.V607M (on ENST00000647909; = p.V599M on NM_003907.3) | Missense Mutation (SNP) | VAF 149/525 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as rs1248680116; called by muse, mutect2, varscan2
- GAPVD1 | c.1579C>T p.P527S | Missense Mutation (SNP) | VAF 56/87 reads (64%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV99783403; called by muse, mutect2, varscan2
- HAUS6 | c.2701G>A p.G901S | Missense Mutation (SNP) | VAF 43/145 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.831); catalogued as rs754329035; called by muse, mutect2, varscan2
- HMCN2 | c.5926C>T p.R1976W | Missense Mutation (SNP) | VAF 26/120 reads (22%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.535); catalogued as rs577965469; called by muse, mutect2, varscan2
- IFIT2 | c.668G>A p.R223H | Missense Mutation (SNP) | VAF 77/109 reads (71%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs757639216; called by muse, mutect2, varscan2
- IGSF9B | c.3104G>A p.R1035H | Missense Mutation (SNP) | VAF 69/411 reads (17%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.98); catalogued as rs372950944; called by muse, mutect2, varscan2
- KCNF1 | c.678G>C p.E226D | Missense Mutation (SNP) | VAF 117/586 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.622); catalogued as COSV54462346; called by muse, mutect2, varscan2
- KIF1C | c.2155C>T p.R719C | Missense Mutation (SNP) | VAF 282/353 reads (80%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.551); catalogued as rs147429300; called by muse, mutect2, varscan2
- KRT82 | c.389G>A p.R130H | Missense Mutation (SNP) | VAF 31/103 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs1224118735; called by muse, mutect2, varscan2
- MDGA1 | c.2789C>T p.P930L | Missense Mutation (SNP) | VAF 46/169 reads (27%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.015); catalogued as rs764414730; called by muse, mutect2, varscan2
- MUC16 | c.27217G>C p.E9073Q | Missense Mutation (SNP) | VAF 161/401 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.581); catalogued as COSV67457150; called by muse, mutect2, varscan2
- NCLN | c.1106C>T p.A369V | Missense Mutation (SNP) | VAF 9/174 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.487); catalogued as rs1330713219; called by muse, mutect2
- NGEF | c.1756C>T p.Q586* | Nonsense Mutation (SNP) | VAF 46/100 reads (46%) | catalogued as COSV99888816; called by muse, mutect2, varscan2
- NRK | c.1009del p.R337Dfs*8 | Frame Shift Del (DEL) | VAF 12/16 reads (75%) | catalogued as rs1336364406; called by mutect2, varscan2
- OBSCN | c.9658G>A p.G3220R | Missense Mutation (SNP) | VAF 78/503 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.248); catalogued as rs1168351001; called by muse, mutect2, varscan2
- OR1C1 | c.433G>C p.V145L | Missense Mutation (SNP) | VAF 44/199 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.033); catalogued as rs754573857; called by muse, mutect2, varscan2
- OR2A5 | c.700C>T p.R234C | Missense Mutation (SNP) | VAF 139/540 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.192); catalogued as rs752112825; called by muse, mutect2, varscan2
- OTOP2 | c.484G>A p.V162I | Missense Mutation (SNP) | VAF 198/540 reads (37%) | SIFT tolerated (0.86); PolyPhen benign (0.038); catalogued as rs373104376; called by muse, mutect2, varscan2
- PAPPA2 | c.1850G>A p.R617H | Missense Mutation (SNP) | VAF 176/317 reads (56%) | SIFT tolerated (0.52); PolyPhen benign (0.005); catalogued as rs541683741, COSV62784683; called by muse, mutect2, varscan2
- PCDH9 | c.2509C>T p.R837C | Missense Mutation (SNP) | VAF 174/213 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60526324; called by muse, mutect2, varscan2
- PCSK4 | c.1273+4C>T | Splice Region (SNP) | VAF 26/217 reads (12%) | catalogued as rs1184838271; called by muse, mutect2, varscan2
- PCSK6 | c.262G>T p.V88L | Missense Mutation (SNP) | VAF 44/113 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs1235099029; called by muse, varscan2
- PHF2 | c.1196C>A p.A399D | Missense Mutation (SNP) | VAF 94/185 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63680343, COSV63680813; called by muse, mutect2, varscan2
- PKN3 | c.2344C>A p.L782M | Missense Mutation (SNP) | VAF 36/387 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV52577360; called by muse, mutect2
- PRDM14 | c.1583C>G p.S528C | Missense Mutation (SNP) | VAF 35/372 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs770947642, COSV52572727; called by muse, mutect2
- PTGDR | c.700C>T p.R234W | Missense Mutation (SNP) | VAF 47/243 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.766); catalogued as rs199602538; called by muse, mutect2, varscan2
- RBMXL2 | c.886C>T p.R296W | Missense Mutation (SNP) | VAF 14/184 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs376176065; called by muse, mutect2
- RNF138 | c.622G>A p.V208I | Missense Mutation (SNP) | VAF 42/60 reads (70%) | SIFT tolerated (0.49); PolyPhen benign (0.074); catalogued as rs1309524763, COSV99857532; called by muse, mutect2, varscan2
- RPS3A | c.598G>T p.A200S | Missense Mutation (SNP) | VAF 31/220 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.021); catalogued as rs781597345; called by muse, mutect2, varscan2
- SLC7A13 | c.677T>G p.L226R | Missense Mutation (SNP) | VAF 11/195 reads (6%) | SIFT tolerated (0.33); PolyPhen benign (0.01); catalogued as rs1161928838; called by muse, mutect2
- SNX20 | c.343C>T p.R115W | Missense Mutation (SNP) | VAF 97/205 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762125596, COSV56058430; called by muse, mutect2, varscan2
- ST13 | c.224C>G p.S75* | Nonsense Mutation (SNP) | VAF 70/190 reads (37%) | catalogued as COSV53423612; called by muse, mutect2, varscan2
- SYMPK | c.1037G>A p.R346H | Missense Mutation (SNP) | VAF 194/420 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs763771090, COSV55616214; called by muse, varscan2
- TCTE1 | c.445G>A p.G149S | Missense Mutation (SNP) | VAF 131/315 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.013); catalogued as COSV65256016; called by muse, mutect2, varscan2
- TNIK | c.749C>T p.A250V | Missense Mutation (SNP) | VAF 24/268 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.246); catalogued as rs373386336, COSV52692394; called by muse, mutect2
- TRIP11 | c.5003A>G p.Q1668R | Missense Mutation (SNP) | VAF 16/278 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); catalogued as rs1468449841; called by muse, mutect2
- UNC79 | c.4478del p.K1493Sfs*12 (on ENST00000393151 / NM_001346218.2; = p.K1316Sfs*12 on NM_020818.5) | Frame Shift Del (DEL) | VAF 44/54 reads (81%) | catalogued as rs760213136; called by mutect2, varscan2
- VMP1 | c.1105G>C p.E369Q | Missense Mutation (SNP) | VAF 78/169 reads (46%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.465); catalogued as COSV51864345, COSV99031686; called by muse, mutect2, varscan2
- ZNF175 | c.1877A>G p.Q626R | Missense Mutation (SNP) | VAF 55/198 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs1224681203; called by muse, mutect2, varscan2
- ZNF283 | c.1130G>A p.C377Y | Missense Mutation (SNP) | VAF 94/224 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs377171671; called by muse, mutect2, varscan2
- ABCA9 | c.3802A>G p.T1268A | Missense Mutation (SNP) | VAF 21/280 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.134); called by muse, mutect2
- AC134980.2 | c.635T>A p.L212Q | Missense Mutation (SNP) | VAF 22/290 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); called by muse, mutect2
- ADGRG6 | c.2582C>T p.T861I | Missense Mutation (SNP) | VAF 50/126 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- ALK | c.1886C>T p.S629F | Missense Mutation (SNP) | VAF 87/411 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- ARHGAP17 | c.1124T>G p.F375C | Missense Mutation (SNP) | VAF 29/161 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ARID3A | c.356C>T p.S119F | Missense Mutation (SNP) | VAF 14/292 reads (5%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.99); called by muse, mutect2
- B3GNT2 | c.439G>A p.A147T | Missense Mutation (SNP) | VAF 121/390 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- BAZ1B | c.457G>C p.D153H | Missense Mutation (SNP) | VAF 40/406 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.365); called by muse, mutect2
- CCDC157 | c.1879T>C p.W627R | Missense Mutation (SNP) | VAF 259/396 reads (65%) | SIFT deleterious (0.02); PolyPhen benign (0.015); called by muse, varscan2
- DCC | c.2063A>C p.K688T | Missense Mutation (SNP) | VAF 133/195 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- DDX42 | c.1484T>G p.F495C | Missense Mutation (SNP) | VAF 209/541 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- DNAH3 | c.10477G>C p.A3493P | Missense Mutation (SNP) | VAF 12/320 reads (4%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.566); called by muse, mutect2
- F7 | c.689T>G p.L230W | Missense Mutation (SNP) | VAF 82/294 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FASLG | c.160C>G p.L54V | Missense Mutation (SNP) | VAF 124/458 reads (27%) | SIFT tolerated (0.86); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- FLNA | c.4582G>T p.E1528* | Nonsense Mutation (SNP) | VAF 29/514 reads (6%) | called by muse, mutect2
- FLT3LG | c.481+1G>T p.X161_splice | Splice Site (SNP) | VAF 43/117 reads (37%) | called by muse, mutect2, varscan2
- FN1 | c.3301A>G p.T1101A | Missense Mutation (SNP) | VAF 81/410 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FPR1 | c.116T>C p.L39P | Missense Mutation (SNP) | VAF 138/380 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- GABRA6 | c.644T>C p.V215A | Missense Mutation (SNP) | VAF 72/180 reads (40%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.597); called by muse, mutect2, varscan2
- GPRIN1 | c.2704G>A p.A902T | Missense Mutation (SNP) | VAF 101/115 reads (88%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.508); called by muse, mutect2, varscan2
- HAL | c.794T>C p.L265P | Missense Mutation (SNP) | VAF 29/638 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- IPO13 | c.2563G>C p.G855R | Missense Mutation (SNP) | VAF 41/326 reads (13%) | SIFT tolerated (0.54); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KLRF2 | c.487G>C p.V163L | Missense Mutation (SNP) | VAF 54/161 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- LAMB4 | c.725G>A p.G242E | Missense Mutation (SNP) | VAF 78/275 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- MYH1 | c.728A>C p.N243T | Missense Mutation (SNP) | VAF 98/342 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.627); called by muse, mutect2, varscan2
- MYH4 | c.874A>G p.I292V | Missense Mutation (SNP) | VAF 51/209 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- NAV1 | c.4072C>T p.R1358* | Nonsense Mutation (SNP) | VAF 247/465 reads (53%) | called by muse, mutect2, varscan2
- NR2C1 | c.1560G>C p.Q520H | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- NUP88 | c.1457C>A p.T486N | Missense Mutation (SNP) | VAF 55/211 reads (26%) | SIFT tolerated (0.63); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR2T4 | c.835G>T p.V279L | Missense Mutation (SNP) | VAF 367/633 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- PABPC4L | c.257C>A p.S86Y | Missense Mutation (SNP) | VAF 79/469 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCSK6 | c.257A>C p.D86A | Missense Mutation (SNP) | VAF 42/112 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, varscan2
- PDE8B | c.2624A>G p.K875R | Missense Mutation (SNP) | VAF 235/305 reads (77%) | SIFT tolerated (0.08); PolyPhen benign (0.206); called by mutect2, varscan2
- PHF8 | c.231G>T p.K77N (on ENST00000357988 / NM_001184896.1; = p.K41N on NM_015107.3) | Missense Mutation (SNP) | VAF 135/165 reads (82%) | SIFT tolerated (0.12); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- PIGG | c.655G>A p.D219N | Missense Mutation (SNP) | VAF 24/358 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PIWIL4 | c.60A>C p.E20D | Missense Mutation (SNP) | VAF 114/212 reads (54%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- PPEF2 | c.1877A>C p.K626T | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT tolerated (0.45); PolyPhen benign (0.024); called by muse, mutect2
- RAB2A | c.91T>C p.F31L | Missense Mutation (SNP) | VAF 43/279 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- RAPGEF6 | c.2642C>G p.P881R | Missense Mutation (SNP) | VAF 121/369 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- RLBP1 | c.245T>G p.V82G | Missense Mutation (SNP) | VAF 179/539 reads (33%) | SIFT tolerated (0.39); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- SEPTIN8 | c.1140G>C p.E380D | Missense Mutation (SNP) | VAF 43/177 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- SFPQ | c.1544C>A p.A515E | Missense Mutation (SNP) | VAF 127/161 reads (79%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SLC25A25 | c.208G>A p.E70K | Missense Mutation (SNP) | VAF 14/297 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.127); called by muse, mutect2
- SLC25A4 | c.281A>G p.K94R | Missense Mutation (SNP) | VAF 18/389 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.019); called by muse, mutect2
- SRCAP | c.8911C>G p.H2971D | Missense Mutation (SNP) | VAF 84/187 reads (45%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TPSB2 | c.621C>G p.D207E | Missense Mutation (SNP) | VAF 38/221 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.017); called by muse, varscan2
- TRIM64C | c.1250C>A p.S417Y | Missense Mutation (SNP) | VAF 330/686 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); called by muse, mutect2, varscan2
- TSG101 | c.187T>C p.Y63H | Missense Mutation (SNP) | VAF 104/123 reads (85%) | SIFT deleterious (0); PolyPhen possibly damaging (0.562); called by muse, mutect2, varscan2
- TTN | c.52981A>T p.T17661S (on ENST00000591111; = p.T10237S on NM_003319.4) | Missense Mutation (SNP) | VAF 32/76 reads (42%) | PolyPhen benign (0); called by muse, mutect2, varscan2
- USH2A | c.5578G>C p.G1860R | Missense Mutation (SNP) | VAF 28/179 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.549); called by muse, mutect2, varscan2
- UTF1 | c.552C>T p.D184= | Splice Region (SNP) | VAF 23/41 reads (56%) | called by muse, mutect2, varscan2
- VCAM1 | c.1977G>C p.Q659H | Missense Mutation (SNP) | VAF 158/297 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- ZGRF1 | c.2356G>C p.E786Q | Missense Mutation (SNP) | VAF 49/139 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.716); called by muse, mutect2, varscan2
- ZNF268 | c.228G>T p.K76N | Missense Mutation (SNP) | VAF 9/287 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.017); called by muse, mutect2
- ZNF718 | c.452T>G p.V151G | Missense Mutation (SNP) | VAF 49/110 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.282); called by muse, mutect2, varscan2
- ADRB1 | c.105C>T p.P35= | Silent (SNP) | VAF 121/200 reads (61%) | catalogued as rs35476499; called by muse, mutect2, varscan2
- ATP13A1 | c.1635G>A p.V545= | Silent (SNP) | VAF 29/480 reads (6%) | called by muse, mutect2
- ATP9A | c.2055G>A p.T685= | Silent (SNP) | VAF 28/257 reads (11%) | catalogued as rs781159334; called by muse, mutect2, varscan2
- CCDC168 | c.7662T>G p.T2554= | Silent (SNP) | VAF 10/210 reads (5%) | called by muse, mutect2
- CGB8 | c.33G>A p.L11= | Silent (SNP) | VAF 118/798 reads (15%) | called by muse, varscan2
- COL20A1 | c.2565T>G p.A855= | Silent (SNP) | VAF 42/257 reads (16%) | called by muse, mutect2, varscan2
- CSMD1 | c.6465C>T p.N2155= (on ENST00000520002; = p.N2154= on NM_033225.6) | Silent (SNP) | VAF 29/77 reads (38%) | catalogued as rs766264947, COSV59336661, COSV59366408; called by muse, mutect2, varscan2
- DNAH10 | c.5031G>A p.A1677= (on ENST00000409039; = p.A1616= on NM_207437.3) | Silent (SNP) | VAF 213/549 reads (39%) | catalogued as rs984373122, COSV68993401; called by muse, mutect2, varscan2
- DOCK7 | c.6099G>C p.V2033= (on ENST00000635253 / NM_001367561.1; = p.V2002= on NM_033407.3) | Silent (SNP) | VAF 104/127 reads (82%) | called by muse, mutect2, varscan2
- DYRK1A | c.1575G>A p.G525= | Silent (SNP) | VAF 60/271 reads (22%) | catalogued as rs762621853; called by muse, mutect2, varscan2
- EPS8L2 | c.516C>A p.A172= | Silent (SNP) | VAF 23/535 reads (4%) | called by muse, mutect2
- FAM133A | c.483G>A p.K161= | Silent (SNP) | VAF 79/91 reads (87%) | called by muse, mutect2, varscan2
- KIAA1109 | c.3375C>T p.N1125= | Silent (SNP) | VAF 66/214 reads (31%) | catalogued as rs766403046; called by muse, varscan2
- KIAA1549 | c.1926G>A p.S642= | Silent (SNP) | VAF 81/147 reads (55%) | catalogued as rs764962649; called by muse, mutect2, varscan2
- KSR2 | c.1827A>G p.Q609= | Silent (SNP) | VAF 58/126 reads (46%) | catalogued as rs753958451; called by muse, mutect2, varscan2
- LRP1B | c.9723T>C p.H3241= | Silent (SNP) | VAF 49/275 reads (18%) | called by muse, mutect2, varscan2
- MITD1 | c.180T>C p.N60= | Silent (SNP) | VAF 173/318 reads (54%) | called by muse, mutect2, varscan2
- NBR1 | c.1224A>G p.A408= | Silent (SNP) | VAF 86/193 reads (45%) | catalogued as rs762888196; called by muse, mutect2, varscan2
- NOX4 | c.243T>G p.A81= | Silent (SNP) | VAF 62/373 reads (17%) | catalogued as COSV54463279; called by muse, mutect2, varscan2
- OR2L5 | c.201C>T p.L67= | Silent (SNP) | VAF 217/368 reads (59%) | catalogued as COSV62364382; called by muse, mutect2, varscan2
- PATE2 | c.282G>A p.K94= | Silent (SNP) | VAF 39/230 reads (17%) | called by muse, mutect2, varscan2
- PCDH15 | c.2694C>T p.A898= | Silent (SNP) | VAF 142/315 reads (45%) | called by muse, mutect2, varscan2
- PTCD1 | c.504A>G p.R168= | Silent (SNP) | VAF 170/690 reads (25%) | called by muse, mutect2, varscan2
- RYR3 | c.7134T>G p.T2378= (on ENST00000389232; = p.T2379= on NM_001036.6) | Silent (SNP) | VAF 150/440 reads (34%) | catalogued as COSV66778872; called by muse, mutect2, varscan2
- SLC6A13 | c.813G>A p.T271= | Silent (SNP) | VAF 127/254 reads (50%) | catalogued as rs147679992, COSV58259322; called by muse, mutect2, varscan2
- TAF1L | c.1692A>T p.T564= | Silent (SNP) | VAF 49/219 reads (22%) | called by muse, mutect2, varscan2
- TCHH | c.4056G>A p.P1352= | Silent (SNP) | VAF 128/744 reads (17%) | called by mutect2, varscan2
- TMC8 | c.174G>C p.V58= | Silent (SNP) | VAF 56/132 reads (42%) | called by muse, mutect2, varscan2
- TTN | c.39426C>T p.F13142= (on ENST00000591111; = p.F5718= on NM_003319.4) | Silent (SNP) | VAF 75/175 reads (43%) | catalogued as rs367744803; ClinVar: likely benign; called by muse, mutect2, varscan2
- VN1R2 | c.957A>G p.A319= | Silent (SNP) | VAF 48/203 reads (24%) | called by muse, mutect2, varscan2
- ZEB2 | c.1627T>C p.L543= | Silent (SNP) | VAF 100/223 reads (45%) | catalogued as COSV57951463; called by muse, mutect2, varscan2
- ZNF524 | c.207G>A p.V69= | Silent (SNP) | VAF 30/212 reads (14%) | catalogued as rs933595277; called by muse, mutect2, varscan2
- ZNF853 | c.724C>T p.L242= | Silent (SNP) | VAF 196/477 reads (41%) | catalogued as rs964259107; called by muse, mutect2, varscan2
- ZSWIM8 | c.2640C>T p.Y880= | Silent (SNP) | VAF 35/154 reads (23%) | called by muse, mutect2, varscan2
- AC009093.3 | chr16:29102126 T>C | 3'Flank (SNP) | VAF 34/428 reads (8%) | called by muse, mutect2
- AC092865.4 | chr12:8390651 T>A | 5'Flank (SNP) | VAF 119/186 reads (64%) | called by muse, varscan2
- ADGRL4 | c.*38T>C | 3'UTR (SNP) | VAF 28/44 reads (64%) | called by muse, mutect2, varscan2
- AOAH | c.128-3332G>C | Intron (SNP) | VAF 56/144 reads (39%) | called by muse, mutect2, varscan2
- CDC16 | c.-28T>C | 5'UTR (SNP) | VAF 21/35 reads (60%) | called by muse, mutect2, varscan2
- CSRP3 | c.*9G>A | 3'UTR (SNP) | VAF 282/367 reads (77%) | catalogued as rs531722178; called by muse, mutect2, varscan2
- CXADRP2 | n.567A>G | RNA (SNP) | VAF 66/226 reads (29%) | called by muse, mutect2, varscan2
- GLT1D1 | c.413-16del | Intron (DEL) | VAF 91/228 reads (40%) | called by mutect2, pindel, varscan2
- RNA5-8SP2 | chr16:34159917 C>T | 5'Flank (SNP) | VAF 50/116 reads (43%) | catalogued as rs760367787; called by muse, mutect2
- RPL34-DT | n.1113C>A | RNA (SNP) | VAF 124/251 reads (49%) | called by muse, mutect2, varscan2
- SPIDR | c.-10G>A | 5'UTR (SNP) | VAF 8/56 reads (14%) | catalogued as rs1393042772; called by muse, mutect2
- SYCE1 | chr10:133568314 G>A | 5'Flank (SNP) | VAF 62/142 reads (44%) | catalogued as COSV58217098; called by muse, mutect2, varscan2
- TAMM41 | c.*38A>T | 3'UTR (SNP) | VAF 38/120 reads (32%) | called by muse, mutect2, varscan2
